Somatic mutation profile of tumor specimen C3L-00969-01 (aliquot CPT0102010009) from CPTAC case C3L-00969, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 40.9 years (14,933 days).
Specimen C3L-00969-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e4c2bc1-b0ca-4bc5-9a7a-81166d73764b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00969-31 (Blood Derived Normal), aliquot CPT0101010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/619211e0-c0a9-40b4-ad65-a9d218d6e457

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Frame Shift Del 6, Intron 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.258dup p.V87Rfs*45 | Frame Shift Ins (INS) | VAF 23/216 reads (11%) | catalogued as rs864622545; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADPRM | c.504G>C p.L168F | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.722); catalogued as COSV65754368, COSV65754936; called by muse, mutect2
- ATP2B2 | c.2239G>A p.E747K (on ENST00000352432; = p.E713K on NM_001683.5) | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs759078548; called by muse, mutect2, varscan2
- CEP85 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV53333014; called by muse, mutect2
- METTL4 | c.1347G>T p.W449C | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170491; called by muse, mutect2
- OR4C12 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs781918776; called by muse, mutect2
- PBRM1 | c.2119del p.E707Kfs*7 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as COSV99968212; called by mutect2, pindel, varscan2
- PRDM2 | c.3085C>G p.P1029A | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99342936, COSV99343111; called by muse, mutect2, varscan2
- ALYREF | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2
- CLEC18A | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CNKSR1 | c.1571C>T p.A524V (on ENST00000374253 / NM_001297647.2; = p.A517V on NM_006314.3) | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- DNAH6 | c.3748T>C p.Y1250H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.544); called by muse, mutect2
- FAM161A | c.1559C>A p.S520Y | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBN1 | c.1114G>C p.V372L | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- HECTD3 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HEPH | c.631C>G p.L211V (on ENST00000343002; = p.L265V on NM_138737.5) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ITIH6 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM5C | c.109_114delinsT p.I37* | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by pindel, varscan2*
- KIF13A | c.3721A>C p.N1241H | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LCT | c.2422C>G p.P808A | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MCCC1 | c.1707_1710del p.N569Kfs*29 | Frame Shift Del (DEL) | VAF 47/235 reads (20%) | called by mutect2, pindel, varscan2
- MSI1 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by mutect2, varscan2
- MSI1 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NKD2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- RGS11 | c.657+2T>A p.X219_splice (on ENST00000397770 / NM_183337.3; = p.X198_splice on NM_003834.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- ROR1 | c.1024C>G p.P342A | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2
- RPL22 | c.252del p.K84Nfs*8 | Frame Shift Del (DEL) | VAF 17/186 reads (9%) | called by mutect2, pindel
- SLC35A5 | c.816T>G p.Y272* | Nonsense Mutation (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- STAG2 | c.2194C>A p.H732N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TP53BP2 | c.3072del p.F1025Lfs*3 (on ENST00000343537 / NM_001031685.3; = p.F896Lfs*3 on NM_005426.2) | Frame Shift Del (DEL) | VAF 28/247 reads (11%) | called by mutect2, pindel, varscan2
- UBR3 | c.4133del p.N1378Mfs*19 | Frame Shift Del (DEL) | VAF 50/323 reads (15%) | called by mutect2, pindel, varscan2
- WDR36 | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- ERVV-1 | c.1143C>T p.V381= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- F2RL3 | c.993C>T p.L331= | Silent (SNP) | VAF 16/239 reads (7%) | called by muse, mutect2
- GCKR | c.525C>T p.V175= | Silent (SNP) | VAF 22/385 reads (6%) | called by muse, mutect2
- IL13RA2 | c.957C>T p.D319= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs199568621; called by muse, mutect2
- LRRC59 | c.330G>C p.L110= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- MUC6 | c.7101G>A p.V2367= | Silent (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- NPAS1 | c.1509G>A p.L503= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- PCSK2 | c.1473C>A p.T491= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- RAP2A | c.144G>C p.S48= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV55354250; called by muse, mutect2, varscan2
- SEMA6A | c.498A>G p.P166= | Silent (SNP) | VAF 12/296 reads (4%) | catalogued as COSV57314523; called by muse, mutect2
- TAS2R20 | c.604C>T p.L202= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV67853624; called by muse, mutect2
- ZMYM4 | c.909C>G p.V303= | Silent (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- CEACAM5 | c.-54T>C | 5'UTR (SNP) | VAF 11/247 reads (4%) | called by muse, mutect2
- IL21R | c.-17+541C>A | Intron (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2
- PHB2 | c.127+9C>T | Intron (SNP) | VAF 22/339 reads (6%) | catalogued as rs188456062; called by muse, mutect2
- RPL10 | c.330-113C>A | Intron (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
